Somatic mutation profile of tumor specimen MP2PRT-PAPPIJ-TMP1-A (aliquot MP2PRT-PAPPIJ-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPPIJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,232 days).
Specimen MP2PRT-PAPPIJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef3491ea-aefa-4507-974d-fd8f3fd079dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPPIJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPPIJ-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8512f008-4173-468b-b045-229c8ac17894

The open-access MAF lists 56 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 3, Frame Shift Ins 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 28/158 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, varscan2
- ARHGEF1 | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 140/290 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs375512672; called by muse, mutect2, varscan2
- BAG3 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 134/334 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs375650805; called by muse, mutect2, varscan2
- CPS1 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 8/233 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99243970; called by muse, mutect2
- ETV6 | c.82delinsCC p.A28Pfs*38 | Frame Shift Ins (INS) | VAF 46/289 reads (16%) | catalogued as COSV67153054, COSV67155184; called by mutect2*, pindel, varscan2*
- IGSF9B | c.3832C>G p.L1278V | Missense Mutation (SNP) | VAF 15/574 reads (3%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.026); catalogued as COSV58063842; called by muse, mutect2
- MECR | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 28/347 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV55284456; called by muse, mutect2
- NCOR2 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 93/229 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs149366660; called by muse, mutect2, varscan2
- PANX3 | c.890G>A p.W297* | Nonsense Mutation (SNP) | VAF 38/262 reads (15%) | catalogued as COSV99421301; called by muse, varscan2
- PNMA6E | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 211/536 reads (39%) | SIFT tolerated (0.06); catalogued as rs1222961145; called by mutect2, varscan2
- SH2D3C | c.985G>A p.E329K (on ENST00000314830 / NM_170600.3; = p.E172K on NM_005489.4) | Missense Mutation (SNP) | VAF 71/372 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs769707691; called by muse, mutect2, varscan2
- TCHH | c.4726G>C p.E1576Q | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as rs754047827; called by muse, mutect2
- ZNF219 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 70/424 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53882273; called by muse, mutect2, varscan2
- BAIAP2L2 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 62/367 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CFAP47 | c.3283G>C p.D1095H | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); called by muse, mutect2
- CHST7 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 16/540 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.194); called by muse, mutect2
- DNAH11 | c.8314G>C p.E2772Q | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ETV6 | c.81dup p.A28Rfs*38 | Frame Shift Ins (INS) | VAF 33/202 reads (16%) | called by mutect2, varscan2
- HEATR5A | c.4178C>G p.S1393C | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- KIAA1217 | c.5070T>A p.D1690E | Missense Mutation (SNP) | VAF 128/291 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LAMA2 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- LRRC49 | c.797C>G p.A266G | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAGEB6B | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.748); called by muse, mutect2
- MAGED1 | c.1618C>G p.L540V | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MAMSTR | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2
- MPDZ | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAT10 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NXPE2 | c.1111C>G p.Q371E | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR10G6 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 49/330 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OR10Z1 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 21/381 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2
- P4HA3 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 14/316 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.269); called by muse, mutect2
- P4HA3 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- PDHA2 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 17/380 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- POP1 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 10/348 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.079); called by muse, mutect2
- PRCP | c.1143A>T p.E381D | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.147); called by muse, mutect2
- RASIP1 | c.2797G>A p.E933K | Missense Mutation (SNP) | VAF 26/444 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); called by muse, mutect2
- RPS6KA6 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC3A1 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 13/433 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); called by muse, mutect2
- SPP1 | c.377C>T p.S126F (on ENST00000395080 / NM_001040058.2; = p.S112F on NM_000582.2) | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STT3B | c.1392G>C p.L464F | Missense Mutation (SNP) | VAF 10/291 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2
- TCHH | c.5185G>T p.E1729* | Nonsense Mutation (SNP) | VAF 28/341 reads (8%) | called by muse, mutect2
- VEPH1 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 17/297 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADAM22 | c.507C>G p.L169= | Silent (SNP) | VAF 12/242 reads (5%) | catalogued as COSV55984165; called by muse, mutect2
- AKR1B15 | c.135T>C p.L45= | Silent (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- COL22A1 | c.633C>G p.G211= | Silent (SNP) | VAF 11/287 reads (4%) | called by muse, mutect2
- DST | c.11070G>A p.Q3690= (on ENST00000361203 / NM_001374722.1; = p.Q1278= on NM_015548.5) | Silent (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- GABRA3 | c.870C>T p.V290= | Silent (SNP) | VAF 16/374 reads (4%) | catalogued as COSV64799430; called by muse, mutect2
- GFM2 | c.2103C>G p.L701= | Silent (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2, varscan2
- GPR63 | c.270C>T p.F90= | Silent (SNP) | VAF 132/272 reads (49%) | called by muse, mutect2, varscan2
- OR6B1 | c.343C>T p.L115= | Silent (SNP) | VAF 30/418 reads (7%) | called by muse, mutect2
- PDZD7 | c.2713C>T p.L905= | Silent (SNP) | VAF 49/267 reads (18%) | called by muse, mutect2, varscan2
- SIRT3 | c.249G>A p.P83= | Silent (SNP) | VAF 53/350 reads (15%) | called by muse, mutect2, varscan2
- SKIV2L | c.2703C>T p.L901= | Silent (SNP) | VAF 14/458 reads (3%) | catalogued as rs748012447, COSV61714949; ClinVar: uncertain significance; called by muse, mutect2
- SLC24A5 | c.741G>A p.L247= | Silent (SNP) | VAF 46/306 reads (15%) | called by muse, varscan2
- EBLN3P | n.4443C>T | RNA (SNP) | VAF 13/386 reads (3%) | called by muse, mutect2
- MLLT10 | c.240+17759C>T | Intron (SNP) | VAF 18/298 reads (6%) | catalogued as rs1340848687; called by muse, mutect2
